Gene-level copy-number profile of tumor specimen C3N-02494-01 from CPTAC case C3N-02494, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 67.0 years (24,467 days).
Specimen C3N-02494-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4af2325-ccb2-4e3f-bb80-951dd2550e96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02494-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/cd2ec346-1a57-412e-adf5-6cdcbed22952

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 194; copy number 1: 20,268; copy number 2: 35,065; copy number 3: 2,038; copy number 4: 532; copy number 5: 182; copy number 6: 4; copy number 7: 18; copy number 8: 4; copy number 10: 76; copy number 18: 16.

Homozygous deletions (total copy number 0; autosomes only): 194 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–746,106, 22 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:19,409,009–26,118,408, 96 genes (broad region; genes not listed).
- chr9:28,598,668–29,636,853, 6 genes (within-gene range 0–1): KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1.
- chr9:89,311,195–91,950,228, 39 genes: CKS2, MIR3153, SECISBP2, SEMA4D, PA2G4P6, AL590233.1, GADD45G, UNQ6494, BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2, OR7E109P, OR7E108P, SYK, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH, NFIL3, AL353764.1, ROR2, PAICSP2, MIR3910-1, MIR3910-2.
- chr9:92,006,062–92,027,824, 2 genes: AL391219.1, HSPE1P22.
- chr16:34,978,744–35,174,093, 14 genes: LINC02184, AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11, NAMPTP3, VPS35P1, VN1R68P, VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4.
- chr16:35,405,747–35,522,465, 15 genes: FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 300 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,065,831–179,465,328, 176 genes, copy number 5 (broad region; genes not listed).
- chr3:180,161,886–182,142,137, 39 genes, copy number 10: RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1.
- chr6:46,652,915–46,954,943, 9 genes, copy number 8–18: SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1.
- chr8:37,559,992–38,601,200, 47 genes, copy number 10–18: AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr8:39,902,275–39,928,790, 1 gene, copy number 7 (within-gene range 2–7): IDO1.
- chr8:39,914,229–39,920,890, 2 genes, copy number 7 (within-gene range 2–7): AC007991.2, AC007991.4.
- chr12:12,875,499–13,387,167, 15 genes, copy number 7: RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1, EMP1, LINC01559.
- chr16:74,377,878–74,441,937, 4 genes, copy number 6: NPIPB15, AC009053.4, CLEC18B, AC009053.3.
- chr18:63,752,935–64,019,779, 6 genes, copy number 5–8: SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8.
- chr18:64,072,158–64,072,653, 1 gene, copy number 5: RPL12P39.

Autosomal genes at a single copy (total copy number 1): 17,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
